Gene-level copy-number profile of tumor specimen TCGA-G2-A2EL-01A from TCGA case TCGA-G2-A2EL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.7 years (28,370 days).
Specimen TCGA-G2-A2EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.69365f99-c023-4764-9ada-3d0676a81e43.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A2EL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7b9cffe-5f8a-42f9-b636-43ee5eb568ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 14,548; copy number 2: 41,687; copy number 3: 3,504.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A2EL-01A-12D-A18E-01): tumor purity 0.98, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:201,288,271–201,927,543, 24 genes (within-gene range 0–1): FLACC1, TRAK2, STRADB, SCYL2P1, Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P.
- chr2:232,697,299–232,860,605, 1 gene (within-gene range 0–1): GIGYF2.
- chr2:232,760,146–233,833,423, 39 genes (within-gene range 0–1): AC064852.1, KCNJ13, RNU6-107P, Y_RNA, SNORC, NGEF, AC106876.1, NEU2, INPP5D, RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P, UGT1A11P, UGT1A8, UGT1A10, UGT1A13P, UGT1A9, UGT1A7, UGT1A6, AC114812.2, UGT1A5, UGT1A4, RPL17P11, UGT1A3, AC114812.3, DNAJB3, UGT1A2P, AC114812.4, AC114812.1, UGT1A1, MROH2A.
- chr5:166,128,498–166,382,599, 2 genes: AC114321.1, AC026403.1.
- chr13:37,854,852–38,350,259, 5 genes (within-gene range 0–2): RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571.
- chr13:82,778,208–83,102,335, 2 genes (within-gene range 0–2): AL445255.1, GYG1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
